Somatic mutation profile of tumor specimen 0DJO5H from CCDI case PBBXHM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (778 days).
Specimen 0DJO5H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e9c2434-4fee-44aa-a499-4a83072038eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65b53c2b-1917-4abf-861a-d7ee4ec90413

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 197/1125 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100052412; called by muse, mutect2, varscan2
- TMEM266 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 173/419 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772544145, COSV66379538, COSV66380103; called by muse, mutect2, varscan2
- NRXN1 | c.1055A>G p.E352G | Missense Mutation (SNP) | VAF 260/734 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SDCCAG8 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 30/551 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); called by muse, mutect2
- SLF1 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 428/1075 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AL592490.1 | c.1299C>T p.N433= | Silent (SNP) | VAF 153/997 reads (15%) | catalogued as rs1266806470, COSV69427268; called by muse, mutect2
- AR | c.1362G>C p.G454= | Silent (SNP) | VAF 61/73 reads (84%) | catalogued as rs1186031724, COSV65953698; called by muse, mutect2, varscan2
- OR2T33 | c.57C>T p.T19= | Silent (SNP) | VAF 54/1123 reads (5%) | called by muse, mutect2
- PCDHB11 | c.150G>A p.K50= | Silent (SNP) | VAF 40/799 reads (5%) | catalogued as COSV53377299; called by muse, mutect2
- SLC25A36 | c.386-97A>G | Intron (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
